Gene-level copy-number profile of tumor specimen MP2PRT-PAPYSK-TMP1-A from MP2PRT case MP2PRT-PAPYSK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,640 days).
Specimen MP2PRT-PAPYSK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7d736287-ac69-4d88-b938-0be174cf11d0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPYSK-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/244c3521-b45e-4aea-8798-1184b1ca2383

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 2: 555; copy number 3: 57; copy number 4: 43,086; copy number 5: 102; copy number 6: 12,151; copy number 7: 119; copy number 8: 2,692; copy number 9: 24; copy number 10: 18; copy number 11: 3; copy number 12: 17; copy number 16: 27; copy number 17: 34.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,734,670–39,741,193, 2 genes: RAB28P1, RBPJP5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 123 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,631,046–39,655,531, 3 genes, copy number 11: FKBP4P2, SDR42E1P1, ATP5F1AP8.
- chr9:39,816,542–40,106,661, 1 gene, copy number 9 (within-gene range 7–9): FGF7P3.
- chr9:39,886,861–40,153,147, 9 genes, copy number 9: RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:62,444,256–62,534,724, 5 genes, copy number 9: BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1.
- chr9:64,878,790–65,193,610, 3 genes, copy number 10–16: AC125634.1, RNU6-1293P, BMS1P12.
- chr14:21,782,993–22,497,718, 85 genes, copy number 9–17 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 17: TRAC.
- chr14:106,675,017–106,811,131, 16 genes, copy number 10 (within-gene range 7–10): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
